Gene-level copy-number profile of tumor specimen TCGA-K4-A4AC-01A from TCGA case TCGA-K4-A4AC, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 83.9 years (30,655 days).
Specimen TCGA-K4-A4AC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.54c4fdd9-a614-4d98-8273-62a4ebd09a9b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-K4-A4AC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2ba2a51c-9c61-4ee6-839c-e5bf0d11140e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 841; copy number 2: 22,133; copy number 3: 22,234; copy number 4: 9,944; copy number 5: 2,760; copy number 6: 1,339; copy number 7: 172; copy number 8: 9; copy number 9: 46; copy number 10: 42; copy number 11: 6; copy number 13: 32; copy number 14: 105; copy number 15: 12; copy number 22: 104.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-K4-A4AC-01A-21D-A26L-01): tumor purity 0.32, ploidy 2.9, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,214,672, 15 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr16:88,984,032–89,557,766, 21 genes (within-gene range 0–2): AC135782.2, AC135782.1, ACSF3, AC135782.3, LINC00304, LINC02138, CDH15, SLC22A31, AC009113.1, ZNF778, AC009113.2, ANKRD11, AC137932.3, AC137932.1, AC137932.2, AC092120.1, AC092120.3, RNU6-430P, AC092120.2, SPG7, AC092123.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 528 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:159,800,511–163,509,595, 151 genes, copy number 9–14 (within-gene range 6–14) (broad region; genes not listed).
- chr1:164,343,005–167,914,215, 79 genes, copy number 7–11 (within-gene range 2–11) (broad region; genes not listed).
- chr6:20,401,879–20,500,276, 5 genes, copy number 7: E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA.
- chr6:21,233,168–22,654,455, 13 genes, copy number 13–15 (within-gene range 3–25): AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1.
- chr6:63,193,072–65,707,226, 24 genes, copy number 7 (within-gene range 3–7): AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1.
- chr8:98,904,603–113,616,958, 222 genes, copy number 7–22 (broad region; genes not listed).
- chr13:73,036,401–74,565,445, 21 genes, copy number 7: PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1, LINC00402, AL353660.1, RNY1P5, RPL21P108, AL355390.1, LINC00381, AL355390.2, LINC00347.
- chr13:76,833,839–77,129,717, 12 genes, copy number 7: AL365394.1, KCTD12, AC000403.1, BTF3P11, ACOD1, RPL7P44, DHX9P1, CLN5, AC001226.2, FBXL3, MYCBP2-AS1, AC001226.1.
- chr13:77,080,511–77,081,190, 1 gene, copy number 7: MYCBP2-AS2.

Autosomal genes at a single copy (total copy number 1): 841. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
